Surgical pathology report (de-identified scan), TCGA case TCGA-HW-A5KM, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-A5KM-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

M

Ref. Physician:

Patient Address:

Location:

Service:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

rear old male with no PMH, patient with right sided numbness/tingling episode suspicious for seizure. Found to have large left hemisphere heterogenous lesion on MRI.

Specimens Submitted:

1: Left temporal brain lesion (fs)

2: Left temporal brain lesion

DIAGNOSIS:

1. Left temporal brain lesion (fs):

TUMOR TYPE:

Diffuse astrocytoma

WHO GRADE:

II

2. Left temporal brain lesion:

TUMOR TYPE:

Diffuse astrocytoma

WHO GRADE:

II

MOLECULAR TESTING / IMMUNOHISTOCHEMISTRY:

1p/19q FISH has been ordered and results will be issued in a separate report

ICD-O-3

Astrocytoma, diffuse 9400/3

Site: Pth Brain, temporal lobe

Site: CGCF Brain, supratentorial

C71.2

NOS

C71.0

9/11/13

Note: The proliferative index (MIB-1/Ki-67) is 2-3%, and focally increases to 5%. IDH1 R132H expression is present in tumor cells. These findings support the above diagnosis.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain

Comment

CG RECUT OD_FIS

CG RECUT OD_FIS

CG RECUT OD_FIS

CG RECUT OD_FIS

CG RECUT OD_FIS

IDH1-H09

NEG CONT

IMM RECUT

MIB-1 (Ki-67)

[page 2 of 2]
Gross Description:

1.) Specimen is a fresh, labeled "left temporal brain lesion," and consists of a 0.8 x 0.6 x 0.6 cm soft, tan-pink portion of brain parenchyma. A squash prep is made and the remainder of the tissue is frozen for intraoperative consultation.

Summary of sections:
FSC-frozen section control

2). The specimen is received fresh, labeled "left temporal brain lesion #2", and consists of multiple fragment of pink tan soft tissue, measuring 1.2 x 0.7 x 2. A fragment of 0.4 cm specimen is sent for TPS. The specimen is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Left temporal brain lesion (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left temporal brain lesion

Block	Sect. Site	PCs
1	U	6

Intraoperative Consultation

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Glioma, favor astrocytoma; not frankly anaplastic on frozen section.
PERMANENT DIAGNOSIS: See final

Diagnostic Discrepancy		

Source: NCI Genomic Data Commons file aae95e39-3aa0-4a1a-af23-2d8602822e59 (TCGA-HW-A5KM.1DA8A802-EC7A-4452-91AD-720ECCE85D8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).